Somatic mutation profile of tumor specimen TCGA-3X-AAVE-01A (aliquot TCGA-3X-AAVE-01A-11D-A417-09) from TCGA case TCGA-3X-AAVE, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.1 years (21,943 days).
Specimen TCGA-3X-AAVE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d237d5b1-4810-423b-9491-28d5d0911a2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3X-AAVE-10A (Blood Derived Normal), aliquot TCGA-3X-AAVE-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3aae8a2a-2b27-4627-abc9-a2b251c32f98

The open-access MAF lists 43 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 12, Nonsense Mutation 2, Intron 2, In Frame Del 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CADM4 | c.711G>T p.E237D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99731423; called by muse, mutect2, varscan2
- CDKN2A | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.975); catalogued as COSV58688112, COSV58700302, COSV58725006; called by muse, mutect2, varscan2
- CHD7 | c.6170G>A p.R2057H | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1318631549; called by muse, mutect2
- CLCC1 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.13); catalogued as rs202122496; called by muse, mutect2, varscan2
- CYP2S1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761773533; called by muse, mutect2, varscan2
- EHMT2 | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as rs933835014, COSV64997963; called by muse, mutect2, varscan2
- FBN3 | c.6989G>A p.R2330Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs757071494; called by muse, mutect2, varscan2
- HMGCL | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764039230, COSV52527508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEX11B | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV100355384; called by muse, mutect2, varscan2
- PLCL1 | c.2470C>T p.R824W | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70836267; called by muse, mutect2, varscan2
- PSMA5 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99600642; called by muse, mutect2, varscan2
- SEC14L4 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs369641628; called by muse, mutect2, varscan2
- ZNF136 | c.770G>A p.C257Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100677983; called by muse, mutect2, varscan2
- ASB7 | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BIRC2 | c.941G>C p.R314T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMSAP1 | c.4679C>A p.S1560* | Nonsense Mutation (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- DOCK10 | c.2667A>T p.L889F | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAXDC2 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IFRD1 | c.741dup p.W248Mfs*12 | Frame Shift Ins (INS) | VAF 19/88 reads (22%) | called by mutect2, pindel, varscan2
- KBTBD8 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- KCNIP4 | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- KRCC1 | c.56_58del p.I19del | In Frame Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- MACF1 | c.5945A>G p.N1982S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- MED16 | c.1733A>G p.D578G | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHF3 | c.1354A>C p.N452H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- RD3 | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2
- TMEM132E | c.829G>A p.A277T (on ENST00000321639; = p.A367T on NM_001304438.2) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZNF703 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- ALPK3 | c.2880G>A p.L960= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- BMP7 | c.753G>A p.T251= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1452830495; called by muse, mutect2, varscan2
- C8B | c.1209C>T p.C403= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- COL20A1 | c.1989C>A p.V663= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- EXD1 | c.678A>G p.Q226= | Silent (SNP) | VAF 71/308 reads (23%) | called by muse, mutect2, varscan2
- FKRP | c.75G>A p.S25= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs1555738032; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR17 | c.42A>G p.P14= | Silent (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- GZF1 | c.1470T>C p.P490= | Silent (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- KLHL20 | c.1386A>G p.L462= | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- MEI1 | c.3558T>C p.S1186= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs779034827; called by muse, mutect2, varscan2
- NET1 | c.951A>G p.K317= (on ENST00000355029 / NM_001047160.3; = p.K263= on NM_005863.5) | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- RTBDN | c.315A>G p.L105= (on ENST00000393233 / NM_001270444.1; = p.L137= on NM_031429.2) | Silent (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- CHMP1A | c.*46_*49dup | 3'UTR (INS) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- MAP3K20 | c.987+3978A>T | Intron (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- POLR2F | c.453-14932T>G | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
